Gene-level copy-number profile of tumor specimen TCGA-D3-A2JO-06A from TCGA case TCGA-D3-A2JO, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 51.0 years (18,627 days).
Specimen TCGA-D3-A2JO-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.def57ac2-4eef-4e00-9de8-f911721701db.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A2JO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d997b4fc-a63f-490b-9c19-29bd555d9d8d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 6,277; copy number 3: 20,385; copy number 4: 22,252; copy number 5: 8,609; copy number 6: 380; copy number 7: 1,636; copy number 8: 97; copy number 10: 25; copy number 11: 90; copy number 12: 54; copy number 14: 8; copy number 20: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A2JO-06A-11D-A194-01): tumor purity 0.33, ploidy 3.63, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,916 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:205,775,559–210,267,241, 107 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr6:167,607–58,438,364, 1,527 genes, copy number 7 (broad region; genes not listed).
- chr10:84,560,443–84,561,263, 1 gene, copy number 14: RPS3AP5.
- chr10:100,463,009–101,194,147, 25 genes, copy number 10: WNT8B, SEC31B, AL133352.1, NDUFB8, HIF1AN, Metazoa_SRP, PAX2, Y_RNA, AL138762.1, SLF2, AL133215.3, MRPL43, SEMA4G, MIR608, AL133215.1, TWNK, LZTS2, PDZD7, SFXN3, AL133215.2, KAZALD1, TLX1NB, TLX1, LINC01514, SMARCE1P7.
- chr22:24,806,169–25,564,719, 28 genes, copy number 8: SGSM1, AL049759.1, TMEM211, KIAA1671, AL022323.2, AL022323.4, AL022323.1, AL022323.3, KIAA1671-AS1, Z99916.2, CRYBB3, Z99916.1, CRYBB2, Z99916.3, AL022332.1, AL022324.4, AL022332.2, IGLL3P, AL022324.1, AL022324.2, LRP5L, AL022324.3, AL008721.1, IGLVIVOR22-1, CRYBB2P1, MIR6817, AL008721.2, AL022329.1.
- chr22:25,580,241–25,581,382, 1 gene, copy number 8: AL022329.2.
- chr22:25,742,144–26,031,045, 1 gene, copy number 8 (within-gene range 2–8): MYO18B.
- chr22:25,876,854–26,006,532, 4 genes, copy number 8: MYO18B-AS1, Z98949.2, RN7SKP169, Z98949.1.
- chr22:33,014,980–37,427,479, 105 genes, copy number 7–20 (within-gene range 6–20) (broad region; genes not listed).
- chr22:40,857,077–40,932,815, 1 gene, copy number 12 (within-gene range 2–12): XPNPEP3.
- chr22:40,917,111–44,010,531, 116 genes, copy number 8–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
